Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0JC, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0JC-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

y/o female with 4.5 cm right breast mass biopsy positive for intraductal carcinoma.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, right axilla (fs)
- 2: SP: Right breast and level 1, plus low level 2 axillary contents
- 3: SP: Level 2 right axillary nodes

DIAGNOSIS:

- 1) SENTINEL NODE #1, LEVEL I, RIGHT AXILLA, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- ADDITIONAL H&E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3) SHOW NO EVIDENCE OF METASTATIC TUMOR.
- 2) BREAST, RIGHT LEVEL I AND LOW LEVEL II AXILLA CONTENTS, MODIFIED RADICAL MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE II/III (MODERATE VARIATION IN SIZE AND SHAPE), MEASURING 5.0 CM IN LARGEST DIMENSION GROSSLY, SEE NOTE.
- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT AND LOWER OUTER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY CARCINOMA IS IDENTIFIED.
- NO DEFINITE EVIDENCE OF VASCULAR INVASION OF CARCINOMA IS NOTED.
- THERE IS PERINEURAL INVASION OF CARCINOMA.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY INVASIVE CARCINOMA IS IDENTIFIED.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES, FIBROCYSTIC CHANGES WITH FLORID DUCTAL HYPERPLASIA AND FIBROADENOMA (1.6 CM) WITH COARSE MICROCALCIFICATIONS.
- ONE BENIGN INTRAPARENCHYMAL LYMPH NODE (0/1).
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): LEVEL I: 0/5.
- RECEPTOR IMMUNOHISTOCHEMISTRY DEMONSTRATES THE FOLLOWING STAINING PATTERNS FOR THE INVASIVE CARCINOMA: ESTROGEN RECEPTOR (ER) POSITIVE, 95% NUCLEAR STAINING WITH STRONG INTENSITY; PROGESTERONE RECEPTOR (PR) POSITIVE, 50% NUCLEAR STAINING WITH MODERATE TO STRONG INTENSITY; AND HER2/NEU

** Continued on next page **

1CD-0-3

carcinoma, infiltrating duct. Nos 8500/3
Site: breast, Nos C50.9 lw 10/22/11

[page 2 of 4]
----- Page 2 of 1 -----
(HERCEPT) NEGATIVE, STAINING INTENSITY OF 0. CONTROLS ARE SATISFACTORY.

NOTE: THE RESULTS OF OTHER IMMUNOHISTOCHEMISTRY STAINS SUPPORT THE ABOVE DIAGNOSIS. SPECIFICALLY, THE TUMOR CELLS ARE POSITIVE FOR CYTOKERATIN 7, BRST-2, AND E-CADHERIN. WHEREAS THE TUMOR CELLS ARE NEGATIVE FOR CK20, SMA, HHF35, SYNAPTOPHYSIN AND CHROMOGRANIN.

- 3) LYMPH NODES, LEVEL II, LEFT AXILLA, DISSECTION:
- FIVE BENIGN LYMPH NODES (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	IMM RECUT	
	NEG CONT	
	ER-C	
	PR-C	
	CMA(HHF35)	
	SMA	
	HER2-C	
	CK7	
	CK20	
	BR2(GCDFP)	
	CHR	
	SYN	
	SYN	
	E-CADHERIN	
	IMM RECUT	
	NEG CONT	
	NEG-HER2	

2

Gross Description:
M.D.

- 1). The specimen is received fresh for frozen section consultation, labeled "Sentinel node number one, level I, right axilla" and consists of two pink tan fatty lymph nodes measuring 1 x 1 x 0.7 and 0.5 x 0.5 x 0.4 cm. The largest lymph node is bisected, and the small lymph node is inked in blue. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

M.D.

** Continued on next page **

[page 3 of 4]
2). The specimen is received fresh labeled, "Right breast and level I and low level II axillary contents" and consists of a breast with attached axillary tail. The breast measures 28.5 x 26 x 4.0 cm with overlying skin ellipse measuring 2.5 x 1.1 cm. Situated centrally on the skin surface is an everted nipple measuring 1.2 x 1.1 x 0.4 cm and areola measuring 4 x 4 cm. The skin is grossly fixed and involved by a mass lesion measuring 5.0 x 4.5 x 3.7 cm situated in the upper and lower outer quadrants between 8 o'clock to 10 o'clock. A suture demarcates the axillary tail which measures 8 x 7 x 1 cm. No tags are present. The posterior surface of the breast is inked black and the specimen is serially sectioned to reveal the mass is abutting the posterior margin. The remaining breast tissue shows fibrofatty cut surface. The axillary tissue is dissected to reveal multiple lymph nodes, ranging in size from 0.3 cm to 1.5 cm. Representative sections are submitted, including all identified lymph nodes. Additionally the container has an irregular skin ellipse and subcutaneous tissue measuring 9.5 x 8.5 x 1.5 cm with overlying skin measuring 8.5 x 6 cm which is grossly unremarkable. Serial sectioning reveals unremarkable fatty cut surface.

Summary of sections:

N - nipple
NB - nipple base
S - skin scar
D - deep margin
T - tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
LN - single lymph nodes
BLN - bisected lymph nodes

M.D.

3). The specimen is received in formalin and is labeled "Level II right axillary nodes". It consists of fragments of fibroadipose tissue measuring 5.5 x 3.5 x 1.5 cm without orientation. Multiple lymph nodes are identified, ranging in size from 0.5 cm to 1.5 cm. All identified lymph nodes are submitted.

Summary of sections:

LNS - whole lymph nodes

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, right axilla (fs)

Block	Sect.	Site	PCs
1		FSC	1

Part 2: SP: Right breast and level 1, plus low level 2 axillary contents

** Continued on next page **

[page 4 of 4]
Block	Sect.	Site	PCs
2		bln	2
1		d	1
2		liq	2
3		ln	3
2		loq	2
1		n	1
1		nb	1
3		s	1
2		t	3
2		uiq	2
2		uoq	2

Part 3: SP: Level 2 right axillary nodes

Block	Sect.	Site	PCs
2		lms	2

Procedures/Addenda:
Addendum

Date Ordered:

Date Complete

Date Reported.

Status: Signed Out
By: MD.

4

Addendum Diagnosis

2) BREAST, RIGHT LEVEL I AND LOW LEVEL II AXILLA CONTENTS; MODIFIED
RADICAL MASTECTOMY:

- THE ORIGINAL DIAGNOSIS ON THIS CASE REMAINS UNCHANGED. THIS ADDENDUM
SERVES TO CLARIFY THAT, ON REPRESENTATIVE SECTIONS, THE INVASIVE CARCINOMA
APPROACHES THE EPIDERMIS OF THE BREAST SKIN, BUT DOES NOT DIRECTLY INVOLVE
THE EPIDERMIS.

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample
examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: NEGATIVE LYMPH NODE.
PERMANENT DIAGNOSIS: SAME

D

** End of Report **

Source: NCI Genomic Data Commons file 76caf189-2385-43c0-a82d-fd2707e3bc20 (TCGA-AO-A0JC.A1F0FEB5-6FEF-4FF7-AA1E-8EAAE551138B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).